Somatic mutation profile of tumor specimen RC-B6S4-TBP1-A (aliquot RC-B6S4-TBP1-A-1-0-D-A94K-47) from RC case RC-B6S4, project RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL). Sex at birth: female; Vital status: Dead; Primary diagnosis: Prolymphocytic leukemia, T-cell type; Tissue or organ of origin: Bone marrow; Age at diagnosis: 76.6 years (27,985 days).
Specimen RC-B6S4-TBP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ef74bf94-b27c-4521-bbc2-829575e21018.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen RC-B6S4-NB1-A (Peripheral Blood Components NOS; tissue type Normal), aliquot RC-B6S4-NB1-A-1-0-D-A94K-47; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cd2f8ec7-4109-4209-a15e-2c974fdd15b0

The open-access MAF lists 18 somatic variants for this specimen: 12 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 5, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FAT1 | c.11081T>C p.V3694A | Missense Mutation (SNP) | VAF 19/201 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV71676565; called by muse, mutect2, varscan2
- FAT4 | c.1915G>A p.G639R | Missense Mutation (SNP) | VAF 75/169 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs963169171; called by muse, mutect2, varscan2
- JAK3 | c.1533G>A p.M511I | Missense Mutation (SNP) | VAF 42/163 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs752661478, COSV71685384, COSV71685422, COSV71685783; called by muse, mutect2, varscan2
- OPTC | c.955G>A p.A319T | Missense Mutation (SNP) | VAF 58/154 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.426); catalogued as rs377265613; called by muse, varscan2
- TRIM2 | c.1102G>A p.E368K (on ENST00000437508; = p.E395K on NM_015271.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 96/248 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.082); catalogued as COSV100107875; called by muse, varscan2
- DOCK4 | c.374T>G p.L125R | Missense Mutation (SNP) | VAF 79/183 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.323); called by muse, varscan2
- ERCC2 | c.1210G>A p.A404T | Missense Mutation (SNP) | VAF 46/121 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- FOXB2 | c.729G>T p.Q243H | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.001); called by mutect2, varscan2
- MMRN2 | c.1195G>C p.E399Q | Missense Mutation (SNP) | VAF 67/201 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- OR2G3 | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 86/206 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM26 | c.533T>C p.L178P | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZMAT5 | c.410T>C p.F137S | Missense Mutation (SNP) | VAF 51/122 reads (42%) | SIFT tolerated (0.31); PolyPhen benign (0.001); called by muse, varscan2
- ASPM | c.1578T>C p.G526= | Silent (SNP) | VAF 75/183 reads (41%) | called by muse, mutect2, varscan2
- GRHL2 | c.1686C>T p.G562= | Silent (SNP) | VAF 58/189 reads (31%) | called by muse, mutect2, varscan2
- MOCS1 | c.438A>G p.E146= | Silent (SNP) | VAF 18/175 reads (10%) | called by muse, mutect2, varscan2
- PAWR | c.324G>A p.S108= | Silent (SNP) | VAF 50/139 reads (36%) | called by muse, varscan2
- PCDHA1 | c.1683C>T p.N561= | Silent (SNP) | VAF 135/380 reads (36%) | catalogued as rs1562135336, COSV65374829; called by muse, mutect2, varscan2
- EDA2R | c.*87C>T | 3'UTR (SNP) | VAF 6/94 reads (6%) | catalogued as rs1215670621; called by muse, mutect2
